Gene-level copy-number profile of tumor specimen TCGA-G3-AAUZ-01A from TCGA case TCGA-G3-AAUZ, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 48.6 years (17,760 days).
Specimen TCGA-G3-AAUZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.045b3b3f-9523-499a-aaa1-5b26d1c39676.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G3-AAUZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/546a20b6-2efa-4b1c-8cb4-cda3b10bbeef

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 6,669; copy number 2: 44,969; copy number 3: 6,607; copy number 4: 1,562; copy number 6: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-G3-AAUZ-01A-11D-A381-01): tumor purity 0.8, ploidy 2.09, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:50,082,169–50,906,856, 1 gene (within-gene range 0–1): DLEU1.
- chr13:50,125,816–51,024,120, 8 genes (within-gene range 0–1): AL137060.3, ST13P4, RPL34P26, AL158195.1, DLEU7, RNA5SP28, RNASEH2B-AS1, RNASEH2B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:158,893,134–159,038,760, 1 gene, copy number 6 (within-gene range 3–6): C4orf45.
- chr4:159,007,119–159,026,527, 2 genes, copy number 6: PSME2P3, FABP5P12.

Autosomal genes at a single copy (total copy number 1): 4,282. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
